Somatic mutation profile of tumor specimen TCGA-N9-A4Q3-01A (aliquot TCGA-N9-A4Q3-01A-11D-A28R-08) from TCGA case TCGA-N9-A4Q3, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IA; Age at diagnosis: 65.8 years (24,031 days).
Specimen TCGA-N9-A4Q3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd9e2cd1-1483-48b0-8cc6-584ea9b75ce2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N9-A4Q3-10B (Blood Derived Normal), aliquot TCGA-N9-A4Q3-10B-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f55f038-8c80-41eb-b02e-a3c44a9d4aef

The open-access MAF lists 44 somatic variants for this specimen: 36 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 7, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 1, Splice Site 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 10/17 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPOX | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs41270025, CM992655; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 42/90 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.97-1G>C p.X33_splice | Splice Site (SNP) | VAF 55/74 reads (74%) | hotspot (GDC flag); catalogued as CS971912, COSV52665806, COSV52762622, COSV52838014; called by muse, mutect2, varscan2
- AIFM1 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as rs1442923435, COSV54856747; called by muse, mutect2, varscan2
- CYP26A1 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763817649, COSV56418505; called by muse, mutect2, varscan2
- FERD3L | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772879781, COSV51762373; called by muse, mutect2, varscan2
- FNDC3A | c.2921G>T p.G974V (on ENST00000492622 / NM_001079673.2; = p.G918V on NM_014923.5) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); catalogued as COSV68132914; called by muse, mutect2, varscan2
- IGHMBP2 | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs373649545; called by muse, mutect2, varscan2
- LRP2 | c.8387G>A p.R2796H | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.607); catalogued as rs552943504, COSV55550196; called by muse, mutect2, varscan2
- MPO | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 79/84 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1396414568; called by muse, mutect2, varscan2
- MXRA5 | c.6250G>A p.G2084R | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs766154632, COSV99028457; called by muse, mutect2, varscan2
- PITPNC1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 104/119 reads (87%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs780864654, COSV55447603; called by muse, mutect2, varscan2
- PRAM1 | c.137A>T p.K46M | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1382401623; called by muse, varscan2
- PROS1 | c.1340A>G p.D447G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1291726191; called by muse, mutect2, varscan2
- AC011448.1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ADGRE1 | c.1492C>A p.H498N | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CDC42BPB | c.3090C>G p.I1030M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- CEP89 | c.1173G>A p.M391I | Missense Mutation (SNP) | VAF 46/346 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CLIP2 | c.2812G>C p.E938Q | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DGKB | c.1811A>G p.E604G | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DPPA3 | c.157G>T p.V53F | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DSN1 | c.222_236del p.Q74_L78del | In Frame Del (DEL) | VAF 60/181 reads (33%) | called by mutect2, pindel, varscan2
- FANCB | c.1947dup p.A650Cfs*8 | Frame Shift Ins (INS) | VAF 14/98 reads (14%) | called by mutect2, pindel, varscan2
- FER1L6 | c.524C>G p.P175R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLG | c.2732C>T p.S911L | Missense Mutation (SNP) | VAF 134/642 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, varscan2
- IWS1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- KANSL3 | c.1834G>C p.E612Q (on ENST00000666923 / NM_001349262.2; = p.E586Q on NM_001115016.3) | Missense Mutation (SNP) | VAF 91/145 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMBRD2 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 22/29 reads (76%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.514C>G p.Q172E | Missense Mutation (SNP) | VAF 11/331 reads (3%) | SIFT tolerated (0.86); PolyPhen benign (0.144); called by muse, mutect2
- PSMD11 | c.1019A>G p.E340G | Missense Mutation (SNP) | VAF 76/84 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINH1 | c.977T>G p.L326R | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TGFBR3 | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- TMEM63A | c.91T>G p.Y31D | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- USP9X | c.4138dup p.R1380Kfs*5 | Frame Shift Ins (INS) | VAF 12/57 reads (21%) | called by mutect2, pindel
- VPS41 | c.173del p.L58Wfs*25 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- ADGRG7 | c.963C>T p.C321= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs1290537154, COSV56303073, COSV99841044; called by muse, mutect2, varscan2
- ANOS1 | c.735C>T p.D245= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as rs188939998, COSV52918184; called by muse, mutect2, varscan2
- ATR | c.7839G>A p.P2613= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs371176601; called by muse, mutect2, varscan2
- KRT33B | c.651C>T p.P217= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs767642130; called by muse, mutect2, varscan2
- PIBF1 | c.87T>C p.V29= | Silent (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- PRAM1 | c.1863C>T p.F621= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- TCF15 | c.399G>A p.S133= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1367356440; called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516108 C>T | 5'Flank (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
